Somatic mutation profile of tumor specimen ALCH-B414-TTP1-A (aliquot ALCH-B414-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B414, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,757 days).
Specimen ALCH-B414-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 333b62f5-4738-4075-9911-3715cd85fedd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B414-NB1-A (Blood Derived Normal), aliquot ALCH-B414-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4736a9a-3eac-43ae-a888-37661a93473f

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 41/676 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AKAP12 | c.3029C>G p.T1010S | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs1050198599; called by muse, mutect2
- CGB2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1248147513; called by muse, mutect2
- KCNH2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs942781074, COSV100059122; called by muse, mutect2
- KIR2DL3 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 27/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1395561727; called by muse, mutect2
- SLC22A13 | c.1337C>A p.T446N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746697760; called by muse, mutect2, varscan2
- GADD45G | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 36/700 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- GSG1L2 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- HTR1A | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2
- MYT1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 32/850 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2
- MED17 | c.981G>T p.V327= | Silent (SNP) | VAF 35/882 reads (4%) | called by muse, mutect2
- PMPCB | c.1347A>T p.T449= | Silent (SNP) | VAF 17/259 reads (7%) | called by muse, mutect2
- XRCC1 | c.553C>T p.L185= | Silent (SNP) | VAF 32/646 reads (5%) | catalogued as COSV53451338; called by muse, mutect2
- ZFPM2 | c.1197C>T p.H399= | Silent (SNP) | VAF 29/680 reads (4%) | catalogued as COSV65872753; called by muse, mutect2
